Somatic mutation profile of tumor specimen C3L-03506-54 (aliquot CPT0280790002) from CPTAC case C3L-03506, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 49.0 years (17,885 days).
Specimen C3L-03506-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c998598d-0f21-42f3-9304-8b9d9988c108.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03506-52 (Buccal Cell Normal), aliquot CPT0280780001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c93f6b6-016f-4e11-9a24-c7e44adca888

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OPLAH | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 19/431 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1459850152; called by muse, mutect2
- CDK1 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHA10 | c.367A>T p.K123* | Nonsense Mutation (SNP) | VAF 86/188 reads (46%) | called by muse, mutect2, varscan2
- ITGB6 | c.1896G>T p.E632D | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); called by muse, varscan2
- MPND | c.159C>A p.G53= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
